FM case AD11007 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas.
https://portal.gdc.cancer.gov/cases/98bdc5a6-a3a8-4a36-a21a-2c61a0b3497b

Male, 57.4 years: Melanoma, NOS (ICD-O-3 8720/3); specimen biopsied or resected from the trachea. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Tumor.
